Somatic mutation profile of tumor specimen 0DLZOJ from CCDI case PBBZKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 15.2 years (5,557 days).
Specimen 0DLZOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a2403c-d506-4cc8-b3b6-7ebbc929a1d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZNB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a72dad9b-376c-414f-84e2-f14faae439ca

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'UTR 2, Nonsense Mutation 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 42/640 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1568659847, CM046052, COSV64198850; ClinVar: pathogenic; called by muse, mutect2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 154/720 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP28 | c.1900C>T p.R634* (on ENST00000383472 / NM_001366230.1; = p.R475* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 46/516 reads (9%) | catalogued as rs773098375, COSV51644954; called by muse, mutect2
- CDH23 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 82/720 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs747238558, COSV54952597; called by muse, mutect2
- DMAC2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 85/495 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782763663; called by muse, mutect2, varscan2
- EPHA5 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 56/549 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as COSV99899764; called by muse, mutect2, varscan2
- KRTAP13-2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 60/912 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1053310564; called by muse, mutect2
- RUBCN | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 78/942 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs768956295; called by muse, mutect2
- SH3KBP1 | c.1859G>A p.R620K | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV65649818; called by muse, mutect2, varscan2
- ZSWIM9 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as rs1342352764; called by muse, mutect2, varscan2
- EYS | c.5468A>G p.Y1823C | Missense Mutation (SNP) | VAF 58/748 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- MAP1S | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.165); called by muse, mutect2
- SOWAHA | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TANGO2 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 76/694 reads (11%) | called by muse, mutect2
- ZNF350 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- CACNG8 | c.606C>T p.Y202= | Silent (SNP) | VAF 48/485 reads (10%) | catalogued as rs1450198304; called by muse, mutect2, varscan2
- NFE2L2 | c.411G>A p.S137= | Silent (SNP) | VAF 36/485 reads (7%) | catalogued as rs773415642, COSV67960153; called by muse, mutect2
- RYR1 | c.1131G>A p.L377= | Silent (SNP) | VAF 30/414 reads (7%) | catalogued as rs1555766901; ClinVar: uncertain significance; called by muse, mutect2
- NEIL1 | c.-23+407C>T | Intron (SNP) | VAF 58/654 reads (9%) | called by muse, mutect2
- OR8J3 | c.*9C>T | 3'UTR (SNP) | VAF 31/473 reads (7%) | called by muse, mutect2
- POU2F3 | chr11:120236657 C>T | 5'Flank (SNP) | VAF 53/516 reads (10%) | catalogued as rs541267299; called by muse, mutect2, varscan2
- SLC25A42 | c.*74G>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | catalogued as rs1183162890, COSV59381028; called by muse, mutect2, varscan2
